Gene-level copy-number profile of tumor specimen HCM-WCMC-0946-C34-01A from HCMI case HCM-WCMC-0946-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Bronchio-alveolar carcinoma, mucinous; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 79.9 years (29,167 days).
Specimen HCM-WCMC-0946-C34-01A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8cf0ce6b-cf6a-4160-b7b2-7a321b89f92e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-WCMC-0946-C34-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/a75f8ebf-22a9-4b9e-b7f1-41caf6a5caca

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 349; copy number 1: 3,953; copy number 2: 52,739; copy number 3: 1,292; copy number 4: 32; copy number 5: 5; copy number 6: 2; copy number 7: 13; copy number 8: 2; copy number 16: 5.

Homozygous deletions (total copy number 0; autosomes only): 349 genes in 43 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:904,834–1,361,777, 48 genes: AL645608.6, AL645608.2, AL645608.4, LINC02593, SAMD11, NOC2L, KLHL17, PLEKHN1, PERM1, AL645608.7, HES4, ISG15, AL645608.3, AL645608.1, AGRN, AL645608.5, AL390719.1, AL645608.8, RNF223, C1orf159, AL390719.3, LINC01342, MIR200B, MIR200A, MIR429, AL390719.2, TTLL10-AS1, TTLL10, TNFRSF18, TNFRSF4, SDF4, B3GALT6, C1QTNF12, AL162741.1, UBE2J2, LINC01786, SCNN1D, ACAP3, MIR6726, PUSL1, INTS11, MIR6727, AL139287.1, CPTP, TAS1R3, DVL1, MIR6808, MXRA8.
- chr1:1,471,765–1,497,848, 1 gene: ATAD3B.
- chr1:1,915,108–2,003,837, 3 genes: CALML6, TMEM52, CFAP74.
- chr1:2,425,980–2,505,532, 3 genes (within-gene range 0–1): PLCH2, AL139246.1, AL139246.4.
- chr1:16,014,028–16,034,050, 2 genes: HSPB7, CLCNKA.
- chr2:232,406,844–232,525,716, 7 genes: ALPG, ECEL1P1, AC068134.2, DIS3L2P1, ALPI, ECEL1, PRSS56.
- chr2:238,100,340–238,168,900, 4 genes: ESPNL, KLHL30, KLHL30-AS1, ERFE.
- chr2:241,188,509–241,225,377, 1 gene: ANO7.
- chr4:1,009,936–1,028,972, 2 genes: FGFRL1, AC019103.1.
- chr4:1,617,915–1,684,261, 2 genes (within-gene range 0–1): FAM53A, Y_RNA.
- chr4:1,793,293–1,808,872, 1 gene: FGFR3.
- chr7:4,775,615–4,794,397, 3 genes: AP5Z1, MIR4656, AC092610.1.
- chr8:142,449,430–142,577,881, 2 genes: ADGRB1, MROH4P.
- chr9:127,716,079–127,735,313, 2 genes (within-gene range 0–2): TTC16, TOR2A.
- chr11:1,012,823–1,262,172, 7 genes (within-gene range 0–1): MUC6, LINC02688, MUC2, MUC5AC, MUC5B, MUC5B-AS1, MIR6744.
- chr11:1,389,899–1,462,689, 1 gene: BRSK2.
- chr12:132,424,504–132,593,698, 8 genes: AC148476.1, AC079031.1, AC079031.2, FBRSL1, AC131212.3, AC131212.2, MIR6763, AC131212.1.
- chr14:100,537,147–100,587,413, 2 genes: BEGAIN, AL845552.2.
- chr14:104,085,686–104,180,894, 5 genes: ASPG, MIR203A, MIR203B, AL359399.1, KIF26A.
- chr14:105,140,982–105,181,323, 4 genes: JAG2, MIR6765, AL512356.1, NUDT14.
- chr15:25,169,337–25,243,695, 41 genes (within-gene range 0–1): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40.
- chr16:527,712–1,510,457, 91 genes (within-gene range 0–2) (broad region; genes not listed).
- chr16:1,512,979–1,514,675, 1 gene (within-gene range 0–2): AL031705.1.
- chr16:1,770,286–1,794,971, 6 genes (within-gene range 0–2): NME3, MRPS34, EME2, SPSB3, NUBP2, IGFALS.
- chr16:2,088,708–2,135,898, 9 genes (within-gene range 0–2): PKD1, MIR1225, AC009065.2, AC009065.5, MIR6511B1, AC009065.6, AC009065.3, Y_RNA, MIR4516.
- chr16:10,718,633–10,725,296, 8 genes: MTCYBP33, MTND6P33, MTND5P33, MTND4P34, MTND4LP24, MTND3P13, MTCO3P24, MTATP6P24.
- chr16:46,469,341–46,649,849, 8 genes: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1.
- chr16:68,367,325–68,370,262, 1 gene (within-gene range 0–2): AC099521.2.
- chr16:70,661,204–70,686,053, 2 genes: MTSS2, AC020763.4.
- chr17:82,078,338–82,098,294, 1 gene: FASN.
- chr19:3,607,247–3,700,468, 4 genes (within-gene range 0–2): CACTIN-AS1, CACTIN, PIP5K1C, AC004637.1.
- chr19:37,024,886–37,025,254, 1 gene (within-gene range 0–1): AC010632.3.
- chr20:63,235,883–63,574,239, 21 genes: BIRC7, MIR3196, NKAIN4, FLJ16779, ARFGAP1, MIR4326, COL20A1, RNU6-994P, CHRNA4, AL121827.1, KCNQ2, AL353658.1, KCNQ2-AS1, EEF1A2, AL121829.1, PPDPF, PTK6, SRMS, AL121829.2, FNDC11, HELZ2.
- chr21:7,744,962–8,761,335, 30 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2, CR381572.1, LINC01666.
- chr21:44,989,864–45,004,727, 3 genes: LINC00163, LINC00165, PICSAR.
- chr22:17,787,652–17,811,497, 2 genes (within-gene range 0–2): AC016026.1, AC016026.2.
- chr22:20,129,456–20,208,524, 4 genes: ZDHHC8, CCDC188, AC007663.2, LINC00896.
- chr22:20,299,760–20,313,216, 1 gene: AC007663.1.
- chr22:29,705,256–29,731,833, 3 genes (within-gene range 0–3): AC004882.1, AC004882.2, CABP7.
- chr22:30,356,635–30,378,658, 1 gene (within-gene range 0–3): CCDC157.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 27 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–135,895, 13 genes, copy number 7: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6.
- chr2:219,538,948–219,547,658, 2 genes, copy number 6: CHPF, AC009955.3.
- chr11:1,947,278–1,984,522, 1 gene, copy number 8 (within-gene range 2–8): MRPL23.
- chr11:1,991,096–2,001,470, 5 genes, copy number 16: LINC01219, H19, AC051649.3, MIR675, AC051649.2.
- chr11:121,447,331–121,453,013, 1 gene, copy number 5 (within-gene range 2–5): AP000977.1.
- chr12:102,196,459–102,197,833, 1 gene, copy number 8 (within-gene range 2–8): PMCH.
- chr13:25,246,201–25,349,800, 3 genes, copy number 5: MTMR6, AL590787.1, NUP58.
- chr15:92,819,540–92,899,701, 1 gene, copy number 5 (within-gene range 2–5): CHASERR.

Autosomal genes at a single copy (total copy number 1): 3,798. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
